Somatic mutation profile of tumor specimen MMRF_1541_1_BM_CD138pos (aliquot MMRF_1541_1_BM_CD138pos_T1_KBS5U_L06416) from MMRF case MMRF_1541, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 57.7 years (21,080 days).
Specimen MMRF_1541_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6db6e26f-374e-4f15-b021-093e73df47e0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1541_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1541_1_PB_Whole_C3_KBS5U_L06463; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8d6197bd-b6a7-402d-a97e-406392fbd1a3

The open-access MAF lists 103 somatic variants for this specimen: 44 protein-altering or splice-affecting, 13 silent, 46 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, 3'UTR 26, Silent 13, Intron 10, RNA 6, Nonsense Mutation 3, Splice Site 2, 5'UTR 2, 3'Flank 2, Frame Shift Del 2, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DIS3 | c.2339G>C p.R780T | Missense Mutation (SNP) | VAF 16/120 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66705570, COSV66707409; called by muse, mutect2, varscan2
- AKAP12 | c.3844G>A p.E1282K | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs368517285; called by muse, mutect2, varscan2
- ANKRD30B | c.3383T>A p.M1128K | Missense Mutation (SNP) | VAF 37/118 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100271665; called by muse, mutect2, varscan2
- APBA2 | c.1826C>T p.S609L | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as rs754328467; called by muse, mutect2, varscan2
- ATM | c.7177T>C p.F2393L | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.49); catalogued as COSV53772688; called by muse, mutect2
- FLRT2 | c.722C>T p.S241L | Missense Mutation (SNP) | VAF 26/168 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as rs755733449, COSV58137055; called by muse, mutect2, varscan2
- KIAA1522 | c.554C>T p.T185M (on ENST00000373480 / NM_001198972.2; = p.T244M on NM_020888.3) | Missense Mutation (SNP) | VAF 54/109 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.188); catalogued as rs759539643; called by muse, mutect2, varscan2
- MAP3K4 | c.4357G>A p.V1453I | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.988); catalogued as rs768779875; called by muse, mutect2, varscan2
- OPA1 | c.2959C>T p.R987C (on ENST00000361510 / NM_130837.3; = p.R932C on NM_015560.3) | Missense Mutation (SNP) | VAF 56/196 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs145710079, CM091835, COSV100655477; called by muse, mutect2, varscan2
- OR2M4 | c.243G>A p.M81I | Missense Mutation (SNP) | VAF 42/143 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.245); catalogued as COSV100140937, COSV60707861; called by muse, mutect2, varscan2
- PRR23A | c.713C>T p.P238L | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.498); catalogued as COSV67214405; called by muse, mutect2, varscan2
- RFXAP | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT tolerated, low confidence (0.26); PolyPhen probably damaging (0.932); catalogued as rs1172888518, COSV99715111; called by muse, mutect2
- SLC24A2 | c.1864G>A p.A622T | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs747399989, COSV53862090; called by muse, mutect2
- TC2N | c.1181G>C p.G394A | Missense Mutation (SNP) | VAF 14/181 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV61748206; called by muse, mutect2
- ZNF555 | c.1373G>C p.G458A | Missense Mutation (SNP) | VAF 21/157 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.936); catalogued as COSV100514813; called by muse, mutect2, varscan2
- ADGRL3 | c.1837C>T p.P613S (on ENST00000506720 / NM_001322402.2; = p.P545S on NM_015236.6) | Missense Mutation (SNP) | VAF 19/161 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ARHGEF26 | c.1811A>T p.E604V | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCDC171 | c.1280T>C p.I427T | Missense Mutation (SNP) | VAF 40/133 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.311); called by muse, mutect2, varscan2
- CKAP5 | c.1405del p.V469Wfs*7 | Frame Shift Del (DEL) | VAF 16/189 reads (8%) | called by mutect2, pindel
- CLCA2 | c.2153A>G p.N718S | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CYLD | c.226G>T p.E76* | Nonsense Mutation (SNP) | VAF 36/104 reads (35%) | called by muse, mutect2, varscan2
- DCAF8L1 | c.550C>T p.Q184* | Nonsense Mutation (SNP) | VAF 3/50 reads (6%) | called by muse, mutect2
- EIF3A | c.1764G>C p.Q588H | Missense Mutation (SNP) | VAF 39/63 reads (62%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- F5 | c.468G>T p.E156D | Missense Mutation (SNP) | VAF 28/47 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- FBXO3 | c.490G>A p.A164T | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.095); called by muse, mutect2
- FLNC | c.976G>T p.V326L | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- GOLM2 | c.913A>G p.N305D | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.979); called by muse, mutect2
- HDGFL2 | c.1916+4A>G | Splice Region (SNP) | VAF 8/27 reads (30%) | called by muse, mutect2, varscan2
- HLA-C | c.16C>G p.P6A | Missense Mutation (SNP) | VAF 4/78 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.665); called by muse, mutect2
- HPR | c.606G>C p.E202D | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.021); called by muse, mutect2
- HTRA3 | c.1069A>C p.I357L | Missense Mutation (SNP) | VAF 12/236 reads (5%) | SIFT tolerated (0.48); PolyPhen benign (0.053); called by muse, mutect2
- ISL1 | c.80A>C p.Q27P | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.248); called by muse, mutect2
- ITGAM | c.2345G>A p.S782N (on ENST00000648685 / NM_001145808.2; = p.S781N on NM_000632.4) | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.894); called by muse, mutect2
- MUC16 | c.17033C>G p.T5678R | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.637); called by muse, mutect2
- P3H1 | c.1721-1G>A p.X574_splice | Splice Site (SNP) | VAF 55/154 reads (36%) | called by muse, mutect2, varscan2
- PIP5K1C | c.1534A>C p.T512P | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); called by muse, mutect2
- PRMT3 | c.1137A>C p.R379S | Missense Mutation (SNP) | VAF 33/285 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- SCML4 | c.1097_1119+13del p.X366_splice | Splice Site (DEL) | VAF 64/204 reads (31%) | called by mutect2, pindel
- SOHLH2 | c.633del p.K211Nfs*2 | Frame Shift Del (DEL) | VAF 19/53 reads (36%) | called by mutect2, pindel, varscan2
- SORCS2 | c.778G>T p.E260* | Nonsense Mutation (SNP) | VAF 12/176 reads (7%) | called by muse, mutect2
- TASOR2 | c.4073A>T p.E1358V | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- TET2 | c.2567G>A p.G856E | Missense Mutation (SNP) | VAF 7/154 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.006); called by muse, mutect2
- TRBV7-3 | c.41dup p.A16Gfs*14 | Frame Shift Ins (INS) | VAF 16/49 reads (33%) | called by mutect2, pindel, varscan2
- XCL2 | c.238G>T p.V80L | Missense Mutation (SNP) | VAF 14/190 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.15); called by muse, mutect2
- ACTL8 | c.1005T>C p.F335= | Silent (SNP) | VAF 5/135 reads (4%) | called by muse, mutect2
- ADAMTS10 | c.861C>T p.L287= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as rs781868632, COSV54353263; called by muse, mutect2, varscan2
- CRISP3 | c.72C>A p.S24= (on ENST00000371159 / NM_001368123.1; = p.S16= on NM_001190986.2) | Silent (SNP) | VAF 9/148 reads (6%) | called by muse, mutect2
- FOSL2 | c.42G>C p.R14= | Silent (SNP) | VAF 13/115 reads (11%) | called by muse, mutect2, varscan2
- KCNJ5 | c.90C>T p.R30= | Silent (SNP) | VAF 40/365 reads (11%) | catalogued as rs201886526, COSV100610491; ClinVar: likely benign; called by muse, mutect2, varscan2
- MEF2A | c.624C>T p.S208= (on ENST00000557942 / NM_001319206.2; = p.S210= on NM_005587.4 and 8 other RefSeq transcripts) | Silent (SNP) | VAF 7/82 reads (9%) | catalogued as COSV100573994; called by muse, mutect2
- MMP15 | c.1866G>A p.R622= | Silent (SNP) | VAF 3/27 reads (11%) | catalogued as rs1167724695; called by muse, mutect2
- OTOG | c.96T>G p.G32= | Silent (SNP) | VAF 7/38 reads (18%) | called by muse, mutect2, varscan2
- P3H2 | c.1233C>G p.V411= | Silent (SNP) | VAF 4/79 reads (5%) | catalogued as COSV100076859; called by muse, mutect2
- PCDH19 | c.2991T>A p.A997= (on ENST00000373034 / NM_001184880.2; = p.A949= on NM_020766.3) | Silent (SNP) | VAF 20/28 reads (71%) | called by muse, mutect2, varscan2
- PTPRZ1 | c.2724T>G p.V908= | Silent (SNP) | VAF 22/217 reads (10%) | called by muse, mutect2, varscan2
- SLC45A1 | c.2028C>T p.D676= | Silent (SNP) | VAF 15/182 reads (8%) | called by muse, mutect2
- TLR4 | c.2196G>A p.K732= (on ENST00000355622 / NM_138554.5; = p.K692= on NM_003266.4) | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as rs769601560; called by mutect2, varscan2
- AC099654.2 | n.1597C>T | RNA (SNP) | VAF 7/10 reads (70%) | called by muse, mutect2
- ADNP | chr20:50889995 T>G | 3'Flank (SNP) | VAF 6/60 reads (10%) | called by muse, mutect2
- ARHGAP31 | c.-229C>T | 5'UTR (SNP) | VAF 3/35 reads (9%) | called by muse, mutect2
- ASB2 | c.908+3300C>G | Intron (SNP) | VAF 57/183 reads (31%) | catalogued as rs1017420878; called by muse, mutect2, varscan2
- ATP5F1E | c.*2376G>C | 3'UTR (SNP) | VAF 15/51 reads (29%) | called by muse, mutect2, varscan2
- B4GAT1 | c.*450T>C | 3'UTR (SNP) | VAF 7/130 reads (5%) | called by muse, mutect2
- BARX2 | c.188-66C>T | Intron (SNP) | VAF 10/95 reads (11%) | called by muse, mutect2, varscan2
- C17orf49 | c.409+27G>A | Intron (SNP) | VAF 6/31 reads (19%) | called by muse, mutect2
- CDK8 | c.*762A>G | 3'UTR (SNP) | VAF 8/68 reads (12%) | called by mutect2, varscan2
- CEACAM3 | c.425-1590G>A | Intron (SNP) | VAF 6/104 reads (6%) | catalogued as rs782811814; called by muse, mutect2
- CFAP43 | c.1442+644A>T | Intron (SNP) | VAF 7/70 reads (10%) | called by mutect2, varscan2
- COPS2 | c.*1621T>C | 3'UTR (SNP) | VAF 13/36 reads (36%) | called by muse, mutect2
- CYP11B2 | c.*23C>A | 3'UTR (SNP) | VAF 8/64 reads (13%) | called by mutect2, varscan2
- CYP2A7P2 | n.356G>A | RNA (SNP) | VAF 6/62 reads (10%) | catalogued as rs540331553; called by mutect2, varscan2
- DMTF1 | c.2173+15T>G | Intron (SNP) | VAF 8/66 reads (12%) | called by mutect2, varscan2
- EIF4E | c.*1180C>G | 3'UTR (SNP) | VAF 21/95 reads (22%) | catalogued as rs903820940; called by muse, mutect2, varscan2
- ENPP4 | c.*2582A>T | 3'UTR (SNP) | VAF 7/86 reads (8%) | called by muse, mutect2
- FAM204A | chr10:118310145 A>G | 3'Flank (SNP) | VAF 3/39 reads (8%) | called by muse, mutect2
- FUS | c.*56C>G | 3'UTR (SNP) | VAF 33/67 reads (49%) | called by muse, mutect2, varscan2
- G3BP2 | c.*1173T>C | 3'UTR (SNP) | VAF 23/65 reads (35%) | called by muse, mutect2, varscan2
- GABRA2 | c.187+21186A>G | Intron (SNP) | VAF 8/78 reads (10%) | called by muse, mutect2
- GABRP | c.*294G>C | 3'UTR (SNP) | VAF 3/36 reads (8%) | called by muse, mutect2
- GRM1 | c.*2471T>A | 3'UTR (SNP) | VAF 9/103 reads (9%) | called by muse, mutect2
- HTR3B | c.-256C>T | 5'UTR (SNP) | VAF 10/91 reads (11%) | catalogued as rs1048942991; called by mutect2, varscan2
- KRTAP4-4 | c.*398A>G | 3'UTR (SNP) | VAF 11/74 reads (15%) | catalogued as rs1339779218; called by muse, mutect2, varscan2
- LNX2 | c.*789T>G | 3'UTR (SNP) | VAF 16/36 reads (44%) | called by muse, mutect2
- NEXMIF | c.*4780A>C | 3'UTR (SNP) | VAF 7/19 reads (37%) | called by muse, mutect2, varscan2
- NPAS4 | c.*72del | 3'UTR (DEL) | VAF 8/63 reads (13%) | catalogued as rs1013946599; called by mutect2, pindel, varscan2
- OGFR | c.171+1223G>A | Intron (SNP) | VAF 8/71 reads (11%) | called by muse, mutect2, varscan2
- OTOR | c.*728T>C | 3'UTR (SNP) | VAF 6/49 reads (12%) | called by muse, mutect2, varscan2
- PCDHB13 | c.*319G>T | 3'UTR (SNP) | VAF 9/92 reads (10%) | called by muse, mutect2, varscan2
- PLA2G4E | c.*927G>A | 3'UTR (SNP) | VAF 27/76 reads (36%) | called by muse, mutect2, varscan2
- RBM33 | c.*5530C>T | 3'UTR (SNP) | VAF 66/174 reads (38%) | called by muse, mutect2, varscan2
- SCN1A | c.*1767G>A | 3'UTR (SNP) | VAF 6/74 reads (8%) | called by muse, mutect2
- SH3BP2 | c.429-123C>T | Intron (SNP) | VAF 28/64 reads (44%) | called by muse, mutect2, varscan2
- SH3PXD2B | c.*3315G>A | 3'UTR (SNP) | VAF 18/79 reads (23%) | catalogued as rs904429681; called by muse, mutect2, varscan2
- SIRPA | c.*742C>T | 3'UTR (SNP) | VAF 7/66 reads (11%) | called by muse, mutect2, varscan2
- SLC9A7P1 | n.690G>A | RNA (SNP) | VAF 5/53 reads (9%) | catalogued as rs1276563846; called by muse, mutect2
- SOCS5P5 | n.376C>T | RNA (SNP) | VAF 7/112 reads (6%) | called by muse, mutect2
- SSPOP | n.12717C>G | RNA (SNP) | VAF 14/112 reads (13%) | called by mutect2, varscan2
- SSR1 | c.*259G>A | 3'UTR (SNP) | VAF 7/112 reads (6%) | called by muse, mutect2
- STK16 | c.*967G>A | 3'UTR (SNP) | VAF 7/141 reads (5%) | called by muse, mutect2
- TMEM165 | c.793-43T>A | Intron (SNP) | VAF 31/61 reads (51%) | called by muse, mutect2, varscan2
- TXLNGY | n.1137T>C | RNA (SNP) | VAF 10/67 reads (15%) | called by muse, mutect2, varscan2
- UBA6 | c.*1061del | 3'UTR (DEL) | VAF 13/61 reads (21%) | called by mutect2, pindel, varscan2
- WT1 | c.*1049del | 3'UTR (DEL) | VAF 6/39 reads (15%) | catalogued as rs568803808, COSV60072460; ClinVar: benign; called by pindel, varscan2
